CGCI case HTMCP-01-01-00003 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/466d7290-7f62-49d7-95f9-e4e51b648024

Demographics
Sex at birth: male; Race: white; Age at index: 33 years; Vital status: Dead; Days to death: -1 day; Cause of death: Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 33.2 years (12,136 days); Year of diagnosis: 1995; Method of diagnosis: Autopsy; Ann Arbor clinical stage: Stage IV; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 0 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Retroperitoneal lymph nodes; Sites of involvement: Adrenal gland, NOS / Brain, NOS / Peritoneum, NOS / Colon, NOS / Liver / Kidney, NOS / Mediastinal soft tissue / Pleura.
   Pathology details: Lymph node involved site: Mediastinal; Lymph nodes tested: 13; Tumor largest dimension diameter: 13 cm.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: -1 day; Disease response: With Tumor.
- Days to follow up: 0 days; Karnofsky performance status: 0.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Negative; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Epstein-Barr Virus (IHC): Positive.
- Epstein-Barr Virus (ISH): Positive.

Other clinical attributes
- Day 0: AIDS risk factors: Wasting Syndrome.
- Day 0: Comorbidities: Cytomegalovirus (CMV).
- Day 0: Risk factors: Cytomegalovirus (CMV).
- Day 0: Height: 142 cm.
- Risk factors: HIV/AIDS.
- Comorbidities: HIV/AIDS.

Biospecimens (3 samples)
- Sample HTMCP-01-01-00003-01D: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-01-00003-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-01-00003-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: Prior aids conditions: Wasting syndrome, due to HIV; History relevant infectious diagnosis: CMV.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Adrenal; Submitted tumor site: Brain; Submitted tumor site: Ascites/Peritoneum; Submitted tumor site: Colon; Submitted tumor site: Liver; Submitted tumor site: Kidney; Submitted tumor site: Mediastinal Soft Tissue; Submitted tumor site: Pleura/Pleural Effusion.
- Primary pathology: Method initial path diagnosis: Other method, specify:; Lymph nodes examined: Yes; Other pos node location: left iliopsoas, pericardial, mediastinal, paratracheal, retroperitoneal, peribronchial, abdominal.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Tests performed: Ebv status malignan cells method: LMP Immunohistochemistry.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-01-00003-01D-03R-1353:
- % tumour top: 90
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-01-00003-01D-03D-1353:
- % tumour top: 90
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-01-00003-11A-01D-1353:
- % tumour top: 0
- % tumour bottom: 0
